Somatic mutation profile of tumor specimen TARGET-10-PARTAK-09A (aliquot TARGET-10-PARTAK-09A-01D) from TARGET case TARGET-10-PARTAK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.7 years (3,901 days).
Specimen TARGET-10-PARTAK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbd0ce26-563c-4cbb-840e-5374f16f276a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARTAK-10A (Blood Derived Normal), aliquot TARGET-10-PARTAK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be4e6be1-407d-41fd-8830-a8224bcf22ba

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 3, Splice Site 2, Frame Shift Ins 1, 3'Flank 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 15/90 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs397507544, CM044932, COSV61005111; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- HSDL2 | c.395+1G>A p.X132_splice | Splice Site (SNP) | VAF 25/157 reads (16%) | catalogued as rs371610846; called by muse, mutect2, varscan2
- MAP7 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.215); catalogued as rs143250781; called by muse, mutect2, varscan2
- RALYL | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.588); catalogued as rs745691095, COSV72818739; called by muse, mutect2, varscan2
- TP53 | c.847_848insCGAGGC p.R282_R283insPR | In Frame Ins (INS) | VAF 16/64 reads (25%) | catalogued as COSV53297573, COSV99037230; called by mutect2, pindel
- BRCC3 | c.799+1G>T p.X267_splice | Splice Site (SNP) | VAF 38/88 reads (43%) | called by muse, mutect2, varscan2
- CREBBP | c.4633T>A p.W1545R | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2D | c.5271_5272insCCCCG p.G1758Pfs*29 | Frame Shift Ins (INS) | VAF 12/89 reads (13%) | called by mutect2, pindel*
- RASIP1 | c.2357C>A p.S786* | Nonsense Mutation (SNP) | VAF 31/139 reads (22%) | called by muse, mutect2, varscan2
- ROBO1 | c.3970A>G p.T1324A | Missense Mutation (SNP) | VAF 81/154 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZCCHC8 | c.670A>T p.R224W | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DST | c.4297-4357G>T | Intron (SNP) | VAF 40/197 reads (20%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-66951C>T | Intron (SNP) | VAF 18/72 reads (25%) | catalogued as rs1487451079, COSV52754916; called by muse, mutect2, varscan2
- SNORD116-24 | chr15:25097774 A>G | 3'Flank (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2
- TYK2 | c.2466+198T>A | Intron (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
